Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2OY, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2OY-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Consultation Report

Patient

Name:

MRN:

DOB:

Gender: F

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Ordering

MD:

Copy To:

Reviewed Initial		

Specimen(s) Received

1. Thyroid: RIGHT HEMI, stitch on upper pole., fresh for tissue banking

Diagnosis

Multifocal papillary carcinoma, dominant oncocytic follicular variant, 2.6 cm, right; mild follicular nodular disease: Thyroid

No pathological diagnosis: Lymph node, right perithyroidal

- Right hemithyroidectomy specimen. See Comment.

ICA-0-3

Carcinoma, papillary, follicular variant

8340/3

Synoptic Data

Procedure: Right hemithyroidectomy
Received: Fresh
Specimen Integrity: Intact
Specimen Size: Right lobe:
6.1 cm
2.7 cm
2.0 cm
Isthmus +/- pyramidal lobe:
2.0 cm
1.1 cm
0.8 cm
Specimen Weight: 16.3 g
Tumor Focality: Multifocal, ipsilateral
Multifocal, midline (isthmus)

Site: Thyroid, NOS C13.9

8/31/11

----- DOMINANT TUMOR -----
Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 2.6cm
Additional dimension: 2.6 cm
Additional dimension: 1.9 cm

Histologic Type:

Papillary carcinoma, follicular variant

per JSS, follicular variant = 100%

[page 2 of 3]
	Papillary carcinoma, oncocytic or oxyphilic variant
	Papillary carcinoma, other variant: focal hobnail cell change (<5%)
	Follicular architecture
	Classical cytomorphology
	Oncocytic or oxyphilic cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
	Distance of invasive carcinoma to closest margin: 0.1mm
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Present, extent minimal
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Right lobe
Tumor Size:	Greatest dimension: 0.1cm
Histologic Type:	Papillary carcinoma, follicular variant
	Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant
	Follicular architecture
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis
	Number of regional lymph nodes examined: 1
	Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically

verified by:

Gross Description

The specimen labeled with the patient's name and as "Thyroid: Right hemi, stitch on upper pole, fresh for tissue banking", consists of a right hemithyroidectomy specimen that is oriented with a suture and weighs 16.3 g. The lobe measures 6.1 cm SI x 2.7 cm ML x 2.0 cm AP and the isthmus measures 2.0 cm SI x 1.1 cm ML x 0.8 cm AP. The external surfaces have fibrous adhesions and are painted with blue dye. No parathyroid glands or no lymph nodes are identified grossly. The lower lobe contains a well delineated nodule that measures 2.6 cm SI x 2.6 cm ML x

[page 3 of 3]
1.9 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A-J lobe, superior to inferior
1K isthmus

Source: NCI Genomic Data Commons file 9f0ff8d5-c0cf-4926-97d9-f1352b0e4863 (TCGA-EM-A2OY.9962DA33-6B07-4433-A4BC-777B4E5942A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).